Somatic mutation profile of tumor specimen MP2PRT-PAUYBD-TMP1-A (aliquot MP2PRT-PAUYBD-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUYBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,025 days).
Specimen MP2PRT-PAUYBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ea34f18-b6b1-4764-a25a-498922fd9b97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYBD-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b407de7-d637-446c-b5a1-98a24f3f20c6

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NXPE1 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- APPBP2 | c.96C>T p.I32= | Silent (SNP) | VAF 72/391 reads (18%) | catalogued as rs1052640798; called by muse, mutect2, varscan2
- CPED1 | c.2997G>A p.S999= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as rs772089376, COSV60009134, COSV60016197; called by muse, mutect2, varscan2
- OTOGL | c.2382T>C p.C794= (on ENST00000547103; = p.C785= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as rs1246985601; called by muse, mutect2, varscan2
- TAPT1 | c.51C>A p.G17= | Silent (SNP) | VAF 392/822 reads (48%) | called by muse, varscan2
